Somatic mutation profile of tumor specimen C3L-00625-02 (aliquot CPT0081470007_1) from CPTAC case C3L-00625, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 34.9 years (12,736 days).
Specimen C3L-00625-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a73337e9-2a82-4dde-a88e-8130f5ed4b7b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00625-31 (Blood Derived Normal), aliquot CPT0081510001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88c5341a-9d61-4b3c-8597-e622db2b938a

The open-access MAF lists 36 somatic variants for this specimen: 19 protein-altering or splice-affecting, 11 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 11, 5'UTR 3, Intron 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 97/600 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.776A>T p.D259V | Missense Mutation (SNP) | VAF 78/467 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as rs745425759, COSV52677009, COSV52679505, COSV53544033; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1H | c.4436G>A p.R1479H | Missense Mutation (SNP) | VAF 30/406 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs776023990, COSV62000838; called by muse, mutect2
- CLCN7 | c.944G>A p.G315D | Missense Mutation (SNP) | VAF 114/834 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1213940371; called by muse, mutect2, varscan2
- DNAH6 | c.6865G>A p.A2289T | Missense Mutation (SNP) | VAF 40/221 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.34); catalogued as rs528704325, COSV52859804; called by muse, mutect2, varscan2
- LCP2 | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 33/233 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.543); catalogued as rs752977011, COSV50455905, COSV99252348; called by muse, mutect2, varscan2
- PDPN | c.461G>A p.R154Q (on ENST00000621990; = p.R230Q on NM_006474.4) | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs147446446; called by muse, mutect2
- RYR3 | c.6233G>C p.G2078A | Missense Mutation (SNP) | VAF 49/357 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV66776470; called by muse, mutect2, varscan2
- TRAT1 | c.349G>A p.V117I | Missense Mutation (SNP) | VAF 48/277 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs149418284, COSV55469471; called by muse, mutect2, varscan2
- CCT6A | c.901T>C p.S301P | Missense Mutation (SNP) | VAF 7/192 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- CNR1 | c.885G>T p.M295I | Missense Mutation (SNP) | VAF 80/436 reads (18%) | SIFT tolerated (0.98); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ESYT3 | c.1825G>A p.V609M | Missense Mutation (SNP) | VAF 139/939 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HNRNPH2 | c.634A>T p.R212W | Missense Mutation (SNP) | VAF 95/565 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KRT7 | c.169G>A p.G57S | Missense Mutation (SNP) | VAF 116/563 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- METRNL | c.546C>A p.H182Q | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.78); called by muse, varscan2
- PDP2 | c.101G>A p.R34K | Missense Mutation (SNP) | VAF 54/400 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRKCQ | c.77A>T p.N26I | Missense Mutation (SNP) | VAF 63/484 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- RPL18 | c.388T>C p.S130P | Missense Mutation (SNP) | VAF 97/561 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- SNRNP200 | c.5732A>T p.D1911V | Missense Mutation (SNP) | VAF 140/818 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ASXL3 | c.6468A>C p.T2156= | Silent (SNP) | VAF 51/367 reads (14%) | called by muse, mutect2, varscan2
- BEND4 | c.627C>T p.N209= | Silent (SNP) | VAF 15/106 reads (14%) | catalogued as rs574971489, COSV72468915; called by muse, mutect2, varscan2
- DNAH11 | c.9666G>A p.V3222= | Silent (SNP) | VAF 59/332 reads (18%) | called by muse, mutect2, varscan2
- H2AC11 | c.267C>T p.R89= | Silent (SNP) | VAF 83/878 reads (9%) | called by muse, mutect2
- INPPL1 | c.1599C>T p.G533= | Silent (SNP) | VAF 76/434 reads (18%) | called by muse, mutect2, varscan2
- ITCH | c.1155G>A p.T385= (on ENST00000262650 / NM_001257137.3; = p.T344= on NM_031483.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 185/733 reads (25%) | catalogued as rs201221876; ClinVar: likely benign; called by muse, mutect2, varscan2
- NEU4 | c.39C>T p.F13= (on ENST00000391969 / NM_001167602.3; = p.F25= on NM_080741.4) | Silent (SNP) | VAF 58/525 reads (11%) | catalogued as rs920176159, COSV57990448; called by muse, mutect2, varscan2
- NME8 | c.312G>A p.P104= | Silent (SNP) | VAF 96/581 reads (17%) | catalogued as rs536359204, COSV52246470; ClinVar: likely benign; called by muse, mutect2, varscan2
- RGS12 | c.1782G>A p.P594= | Silent (SNP) | VAF 47/356 reads (13%) | catalogued as rs751083722; called by muse, mutect2, varscan2
- SLITRK3 | c.2892G>A p.P964= | Silent (SNP) | VAF 35/198 reads (18%) | catalogued as rs781561672, COSV53850899, COSV99578396; called by muse, mutect2, varscan2
- WDR97 | c.987C>T p.F329= | Silent (SNP) | VAF 95/532 reads (18%) | called by muse, mutect2, varscan2
- CLDN16 | c.-96C>G | 5'UTR (SNP) | VAF 94/673 reads (14%) | called by muse, mutect2, varscan2
- MMGT1 | c.-252C>G | 5'UTR (SNP) | VAF 103/934 reads (11%) | called by muse, mutect2, varscan2
- PDGFD | c.125-36588G>A | Intron (SNP) | VAF 55/257 reads (21%) | catalogued as rs777102812, COSV56395204; called by muse, mutect2
- PRKAG3 | c.775-12C>T | Intron (SNP) | VAF 114/772 reads (15%) | catalogued as rs753669652; called by muse, varscan2
- UBBP4 | n.537G>A | RNA (SNP) | VAF 158/1208 reads (13%) | called by muse, mutect2, varscan2
- VAMP3 | c.-38C>A | 5'UTR (SNP) | VAF 99/566 reads (17%) | called by muse, mutect2, varscan2
